Somatic mutation profile of tumor specimen TCGA-05-4396-01A (aliquot TCGA-05-4396-01A-21D-1855-08) from TCGA case TCGA-05-4396, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 76.9 years (28,094 days).
Specimen TCGA-05-4396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 150f8a17-f186-4f5f-8368-824ff22f2ebd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4396-10A (Blood Derived Normal), aliquot TCGA-05-4396-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc70453f-1898-4235-95d2-bb163a09d767

The open-access MAF lists 257 somatic variants for this specimen: 205 protein-altering or splice-affecting, 48 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 48, Nonsense Mutation 17, Frame Shift Del 5, Splice Site 3, 3'UTR 1, 5'Flank 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 43/122 reads (35%) | catalogued as rs377160065, CM075939; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs397517180, CM070284, COSV67675939; ClinVar: pathogenic; called by mutect2, varscan2
- AARS1 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55749853; called by muse, varscan2
- ABCD3 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59867964; called by muse, mutect2, varscan2
- ABRAXAS2 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53718737; called by muse, varscan2
- ACOX1 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99504049; called by mutect2, varscan2
- AMER1 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV57670023; called by muse, varscan2
- AMOTL1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759915086, COSV58570823; called by mutect2, varscan2
- AOC1 | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.539); catalogued as COSV62871200; called by muse, mutect2, varscan2
- APOB | c.2917C>A p.L973M | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs886055592, COSV51955068; ClinVar: uncertain significance; called by mutect2, varscan2
- ARID2 | c.322del p.E108Rfs*107 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as COSV100536762; called by mutect2, pindel, varscan2
- ARID2 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57615891; called by muse, mutect2, varscan2
- ASTN1 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 178/250 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.413); catalogued as COSV56068276; called by mutect2, varscan2
- ASTN2 | c.1591G>T p.G531* (on ENST00000313400 / NM_001365069.1; = p.G480* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV57752943, COSV57821120; called by muse, mutect2, varscan2
- ASXL1 | c.1634G>C p.R545P | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60123826; called by muse, mutect2, varscan2
- ASXL3 | c.5396C>A p.P1799Q | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV52481315; called by muse, mutect2, varscan2
- ATP13A5 | c.3382G>T p.A1128S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV60876195; called by muse, mutect2, varscan2
- B4GALT5 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 60/174 reads (34%) | catalogued as COSV65494534, COSV65495423; called by muse, varscan2
- CARNS1 | c.2129A>T p.D710V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57055480; called by muse, mutect2, varscan2
- CATSPER3 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV50946788; called by muse, mutect2, varscan2
- CBLN2 | c.235A>T p.T79S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV54053274; called by muse, varscan2
- CCDC160 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV100892084; called by muse, mutect2, varscan2
- CCNA2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52659899; called by mutect2, varscan2
- CD2BP2 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 83/111 reads (75%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV59769996; called by muse, mutect2, varscan2
- CFAP69 | c.1992G>T p.L664F | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60188796; called by muse, mutect2, varscan2
- CFTR | c.3603T>A p.D1201E | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV50113028; called by muse, mutect2, varscan2
- CLIC4 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 34/56 reads (61%) | catalogued as COSV65525473, COSV65527838; called by muse, mutect2, varscan2
- CNR1 | c.229A>T p.N77Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62992074; called by mutect2, varscan2
- CNTLN | c.3455A>G p.D1152G | Missense Mutation (SNP) | VAF 120/186 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs768323927, COSV52099260; called by muse, mutect2, varscan2
- CNTN4 | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.472); catalogued as COSV61878354, COSV61881847; called by mutect2, varscan2
- CNTNAP2 | c.3946C>T p.P1316S | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV62265792; called by muse, mutect2, varscan2
- COL22A1 | c.3844G>T p.G1282C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57363191; called by muse, mutect2, varscan2
- CRISPLD1 | c.1055G>T p.W352L | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV51553489; called by mutect2, varscan2
- CST9L | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV65407786, COSV65408423; called by mutect2, varscan2
- CTTNBP2 | c.3770C>G p.S1257C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV50389825, COSV50489306; called by muse, mutect2, varscan2
- DCAF8L1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV71595558; called by muse, mutect2, varscan2
- DCC | c.1782T>A p.Y594* | Nonsense Mutation (SNP) | VAF 46/142 reads (32%) | catalogued as COSV59139772; called by muse, varscan2
- DEUP1 | c.909C>A p.C303* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV53217336, COSV99977000; called by muse, mutect2, varscan2
- DNAH7 | c.5911C>A p.P1971T | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV56789216; called by muse, mutect2, varscan2
- DNAH7 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 97/252 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.036); catalogued as COSV100415129, COSV56789230; called by muse, mutect2, varscan2
- DNAH9 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs765666122, COSV52379331; called by mutect2, varscan2
- DOCK10 | c.4973C>A p.T1658N | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV51429401; called by muse, varscan2
- DST | c.18183G>C p.L6061F (on ENST00000361203 / NM_001374722.1; = p.L3758F on NM_015548.5) | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55043126; called by muse, mutect2, varscan2
- DST | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56850156; called by muse, mutect2
- DUOXA2 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs768538497, COSV50995029; called by muse, mutect2, varscan2
- DYNC2H1 | c.4013A>T p.Y1338F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV62108241; called by muse, mutect2, varscan2
- DYNC2LI1 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53182874, COSV53185545; called by muse, mutect2, varscan2
- EIF2B3 | c.1190C>G p.T397S | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV64518917; called by muse, varscan2
- ELF3 | c.221A>T p.D74V | Missense Mutation (SNP) | VAF 106/158 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV62840602; called by muse, mutect2, varscan2
- EPG5 | c.5762G>T p.S1921I | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV56356712; called by muse, mutect2, varscan2
- EVC | c.2424A>C p.K808N | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV99382682; called by muse, mutect2
- F11 | c.1748A>T p.H583L | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs776663832, COSV53003404; called by muse, varscan2
- FAM186B | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV57724238, COSV99218405; called by muse, mutect2, varscan2
- FAT1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV71676210; called by muse, mutect2, varscan2
- FBXO4 | c.961T>C p.S321P | Missense Mutation (SNP) | VAF 266/407 reads (65%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV55854412; called by muse, mutect2, varscan2
- FCN2 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV52479253; called by muse, mutect2, varscan2
- FGGY | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV58046951; called by muse, mutect2, varscan2
- FIGNL1 | c.1056G>T p.Q352H | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as COSV63554151; called by mutect2, varscan2
- FLG2 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 215/272 reads (79%) | catalogued as COSV66170208; called by muse, mutect2, varscan2
- FLNC | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57966112; called by muse, varscan2
- FLT3 | c.869A>C p.K290T | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV54072814; called by muse, mutect2, varscan2
- FOXP2 | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as rs777560011, COSV63494754; called by mutect2, varscan2
- FRY | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV66581300; called by muse, mutect2
- FZD10 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV57476168; called by muse, mutect2, varscan2
- GABRQ | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV64784143; called by muse, varscan2
- GPATCH1 | c.1637G>T p.R546L | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as COSV50129285; called by muse, mutect2, varscan2
- GPHN | c.1579C>T p.R527C (on ENST00000315266 / NM_001377519.1; = p.R560C on NM_020806.5) | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1567363565, COSV59472785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR55 | c.459C>A p.S153R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV67408845; called by muse, varscan2
- GRID1 | c.1228C>A p.R410S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV100022404, COSV60016469, COSV60056647; called by muse, mutect2, varscan2
- GUCY1B1 | c.548A>T p.E183V | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV52379457; called by mutect2, varscan2
- HGF | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV55957167, COSV55957898; called by muse, mutect2, varscan2
- HIBCH | c.881A>T p.E294V | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV62893415; called by mutect2, varscan2
- HIVEP3 | c.5801A>G p.Q1934R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56024721; called by muse, mutect2, varscan2
- HJURP | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV100982594, COSV64979676; called by muse, mutect2, varscan2
- HOXA3 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562708378, COSV57829208; called by muse, mutect2, varscan2
- HRH4 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | catalogued as COSV56929833; called by muse, mutect2, varscan2
- ICE1 | c.5320C>T p.Q1774* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV56819516, COSV56833659; called by mutect2, varscan2
- IFT172 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1007620906, COSV53137530, COSV53140281; called by muse, mutect2, varscan2
- IL12RB2 | c.1894T>A p.C632S | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV52027757; called by muse, mutect2, varscan2
- IL24 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 20/343 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99686582; called by muse, mutect2
- IP6K2 | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53663985; called by muse, varscan2
- IQCF1 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 303/776 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV58823300, COSV58824183; called by muse, mutect2, varscan2
- KCNC1 | c.799T>G p.C267G | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56399029; called by muse, mutect2, varscan2
- KCND3 | c.442A>T p.M148L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100138639, COSV56190592; called by muse, mutect2, varscan2
- KCNK16 | c.382T>C p.Y128H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64678038, COSV64679606; called by muse, varscan2
- KCNK18 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV57973469; called by muse, mutect2, varscan2
- KDM5C | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 46/62 reads (74%) | catalogued as COSV64770575; called by mutect2, varscan2
- KIAA1755 | c.2242A>T p.K748* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV54081302; called by muse, mutect2, varscan2
- KIAA2026 | c.2504G>T p.R835L | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67358043; called by muse, mutect2, varscan2
- KLHL1 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.444); catalogued as COSV64785179, COSV64785535; called by muse, mutect2, varscan2
- KMT2D | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV56491908; called by muse, mutect2, varscan2
- KPNA6 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV65362304; called by muse, varscan2
- LRP1B | c.13659+1del p.X4553_splice | Splice Site (DEL) | VAF 24/84 reads (29%) | catalogued as COSV67231952, COSV67272133; called by mutect2, pindel, varscan2
- LRP1B | c.8503G>A p.D2835N | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67271921; called by mutect2, varscan2
- LRP1B | c.5018C>A p.T1673K | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV67279819; called by muse, mutect2, varscan2
- LRRN2 | c.2066C>A p.P689H | Missense Mutation (SNP) | VAF 111/150 reads (74%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV65784888; called by muse, mutect2, varscan2
- ME2 | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58425197; called by muse, varscan2
- MGAM | c.5263G>T p.G1755W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72074995; called by mutect2, varscan2
- MLLT10 | c.2331G>T p.Q777H (on ENST00000307729 / NM_001195626.3; = p.Q793H on NM_004641.3) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57005554; called by muse, mutect2, varscan2
- MMP20 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as COSV52777170; called by muse, mutect2, varscan2
- MUC16 | c.22157T>C p.V7386A | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.179); catalogued as COSV67497614; called by muse, mutect2, varscan2
- MUC16 | c.21506C>A p.T7169N | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV67497627; called by muse, mutect2, varscan2
- MUC16 | c.7057G>T p.D2353Y | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV67497638; called by muse, varscan2
- MYLK | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs532659627, COSV60611222, COSV60615080, COSV60623949; called by muse, mutect2, varscan2
- MYO1A | c.477T>A p.F159L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55657761; called by muse, varscan2
- NCOA6 | c.3686C>G p.P1229R | Missense Mutation (SNP) | VAF 139/398 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV62865957, COSV62868473; called by muse, mutect2, varscan2
- NCR1 | c.504C>A p.Y168* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV52555417, COSV52555583; called by muse, mutect2, varscan2
- NDST3 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs150758016; called by muse, varscan2
- NEK5 | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62882237; called by muse, varscan2
- NEUROD6 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.073); catalogued as rs1001962404, COSV51773762; called by muse, mutect2, varscan2
- NEXMIF | c.3719G>T p.G1240V | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as COSV99029806; called by muse, varscan2
- NEXMIF | c.3718G>T p.G1240C | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV50026181; called by muse, varscan2
- NLGN4X | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52038921; called by muse, mutect2, varscan2
- NLRP3 | c.1856T>A p.L619Q | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.38); PolyPhen benign (0.085); catalogued as COSV60231734; called by muse, mutect2, varscan2
- NLRP4 | c.2247C>A p.N749K | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100016111, COSV56724552; called by muse, mutect2, varscan2
- NOD2 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56055194; called by muse, mutect2, varscan2
- NOX4 | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV54465958, COSV99629302; called by muse, mutect2, varscan2
- NPAP1 | c.117C>A p.H39Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100274681, COSV61511985; called by muse, mutect2, varscan2
- OR2L3 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 83/147 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs970687072, COSV100742082; called by mutect2, varscan2
- OR2T4 | c.669C>A p.D223E | Missense Mutation (SNP) | VAF 138/202 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV63545225; called by muse, mutect2, varscan2
- OR51E2 | c.945G>T p.Q315H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV67808912; called by mutect2, varscan2
- OR5D16 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.597); catalogued as COSV65722237; called by muse, mutect2, varscan2
- OR5F1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53549098; called by muse, mutect2, varscan2
- OR5J2 | c.398C>A p.T133N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56623484; called by muse, mutect2, varscan2
- OR5P3 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100103281; called by mutect2, varscan2
- OR8H2 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57943871, COSV57947662, COSV57947683; called by muse, varscan2
- PCCB | c.201G>T p.R67S | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs747053913, CM034105, COSV52445323; called by muse, mutect2, varscan2
- PCDHB5 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 35/61 reads (57%) | catalogued as COSV50664345; called by muse, mutect2, varscan2
- PCDHGA10 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 67/103 reads (65%) | catalogued as COSV54043871, COSV99538322; called by muse, mutect2, varscan2
- PGK2 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59165792; called by muse, mutect2, varscan2
- PHACTR2 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV59854458, COSV59859974, COSV99992009; called by muse, mutect2, varscan2
- PIK3R4 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV63244219; called by mutect2, varscan2
- PITPNM2 | c.1430C>G p.P477R | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54909548; called by muse, mutect2, varscan2
- PKN2 | c.2093A>T p.E698V | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60135834; called by mutect2, varscan2
- PLRG1 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV57424848; called by muse, mutect2, varscan2
- POLE | c.4272G>T p.E1424D | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs763572490, COSV57691774; called by muse, mutect2, varscan2
- POSTN | c.1791+1G>C p.X597_splice | Splice Site (SNP) | VAF 47/92 reads (51%) | catalogued as COSV65714901; called by muse, mutect2, varscan2
- PRCC | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54858839; called by muse, mutect2, varscan2
- PRSS1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs199422123, CM063077, COSV61197755; ClinVar: uncertain significance; called by muse, varscan2
- RAB11FIP2 | c.1186C>G p.R396G | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV62925240, COSV62926281; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1569-1G>T p.X523_splice | Splice Site (SNP) | VAF 61/146 reads (42%) | catalogued as COSV50260139; called by muse, mutect2, varscan2
- RAB2A | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52914502; called by muse, mutect2, varscan2
- RBM19 | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV55699118; called by muse, mutect2, varscan2
- RNF165 | c.647C>G p.P216R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53978411; called by muse, varscan2
- ROBO2 | c.4062G>C p.Q1354H | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV59942462; called by muse, varscan2
- RYR2 | c.6404G>T p.G2135V | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63701065, COSV63717981; called by muse, varscan2
- RYR2 | c.8906C>A p.P2969H | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63712942, COSV63717988; called by mutect2, varscan2
- SELP | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 167/246 reads (68%) | SIFT tolerated (0.68); PolyPhen benign (0.167); catalogued as COSV55259264; called by muse, mutect2, varscan2
- SI | c.2980G>T p.G994C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs768991830, COSV100016383, COSV52303350; called by muse, mutect2, varscan2
- SLC39A2 | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as COSV53871268; called by muse, mutect2, varscan2
- SLC44A1 | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV58267706; called by muse, mutect2, varscan2
- SLC5A4 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV56674313; called by muse, mutect2, varscan2
- SLC8A3 | c.1544C>A p.S515Y | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV63527219; called by mutect2, varscan2
- SLITRK6 | c.2223C>A p.N741K | Missense Mutation (SNP) | VAF 186/488 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV68389485, COSV68391891; called by muse, mutect2, varscan2
- SNX13 | c.2213A>T p.Q738L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV68068506; called by muse, mutect2, varscan2
- SRCAP | c.3344G>T p.R1115L | Missense Mutation (SNP) | VAF 159/277 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.694); catalogued as rs748378605, COSV52682019; called by muse, mutect2, varscan2
- STAG2 | c.2991G>C p.L997F | Missense Mutation (SNP) | VAF 55/73 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV54356551; called by muse, mutect2, varscan2
- STT3A | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.977); catalogued as COSV67065607; called by muse, varscan2
- SWI5 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60793278; called by muse, mutect2, varscan2
- TAF1L | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54271044; called by muse, mutect2, varscan2
- TANGO6 | c.1214C>G p.S405* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as COSV55773603; called by muse, mutect2, varscan2
- TARS3 | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV60109815; called by mutect2, varscan2
- TAX1BP1 | c.920T>A p.L307* | Nonsense Mutation (SNP) | VAF 61/136 reads (45%) | catalogued as COSV55297390; called by mutect2, varscan2
- TBC1D9 | c.3475G>C p.D1159H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV71309321; called by muse, varscan2
- TENM1 | c.4816C>G p.Q1606E | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV64445021; called by muse, varscan2
- TENM1 | c.959C>G p.A320G | Missense Mutation (SNP) | VAF 106/128 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64445033; called by muse, mutect2, varscan2
- TGFB1I1 | c.226G>T p.A76S (on ENST00000394863 / NM_001042454.3; = p.A59S on NM_015927.4) | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV62359327; called by muse, mutect2, varscan2
- THBS2 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64682493; called by muse, mutect2, varscan2
- TLR4 | c.1384G>C p.A462P (on ENST00000355622 / NM_138554.5; = p.A422P on NM_003266.4) | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.711); catalogued as COSV62924392; called by muse, mutect2, varscan2
- TMTC1 | c.493G>A p.V165I (on ENST00000539277 / NM_001193451.2; = p.V57I on NM_175861.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs372238552; called by muse, varscan2
- TNN | c.2762C>T p.S921F | Missense Mutation (SNP) | VAF 71/95 reads (75%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV53436959, COSV99511971; called by muse, mutect2, varscan2
- TP53 | c.416del p.K139Rfs*31 | Frame Shift Del (DEL) | VAF 24/43 reads (56%) | catalogued as COSV52987330, COSV53124329; called by mutect2, pindel, varscan2
- TRIM29 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV59282336; called by muse, mutect2, varscan2
- TRIM49 | c.1194G>T p.M398I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.043); catalogued as COSV100316270; called by muse, mutect2, varscan2
- TRIML2 | c.1115T>A p.V372D | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58720103; called by muse, varscan2
- TSHZ2 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780341360, COSV61591986; called by mutect2, varscan2
- UMPS | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51739266; called by mutect2, varscan2
- USP28 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV50170939; called by mutect2, varscan2
- USP9X | c.2324G>T p.W775L | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61075887, COSV61075969; called by muse, mutect2, varscan2
- XIRP2 | c.1612G>T p.V538F (on ENST00000628543; = p.V713F on NM_152381.6) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV54737640; called by muse, varscan2
- ZDBF2 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65630581; called by mutect2, varscan2
- ZEB2 | c.2458T>G p.L820V | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57967333; called by muse, mutect2, varscan2
- ZNF454 | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 54/71 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0.136); catalogued as COSV60770553; called by muse, mutect2, varscan2
- ZNF621 | c.1102G>T p.V368F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV59459309; called by mutect2, varscan2
- ZNF623 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71697378; called by mutect2, varscan2
- ABHD1 | c.1187C>A p.A396D | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BEND2 | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C12orf43 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN25 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, varscan2
- DHX38 | c.3281G>T p.R1094L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); called by muse, varscan2
- F3 | c.164_165del p.L55* | Frame Shift Del (DEL) | VAF 40/282 reads (14%) | called by mutect2, pindel, varscan2
- FNBP1L | c.1588G>A p.E530K (on ENST00000271234 / NM_001164473.2; = p.E472K on NM_017737.5) | Missense Mutation (SNP) | VAF 114/154 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by mutect2, varscan2
- HOPX | c.158A>T p.Q53L (on ENST00000317745; = p.Q71L on NM_032495.6) | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNG2 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGRN1 | c.108C>G p.H36Q | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2L3 | c.566T>A p.M189K | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OTOGL | c.2897A>T p.Y966F (on ENST00000547103; = p.Y957F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PLXNA4 | c.41A>T p.H14L | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by mutect2, varscan2
- PRKDC | c.7873C>T p.L2625F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, varscan2
- SCLT1 | c.842A>C p.Q281P | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNAP23 | c.338del p.N113Mfs*2 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | called by mutect2, pindel, varscan2
- SQOR | c.624del p.M209Cfs*78 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- SUCNR1 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCF23 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, varscan2
- WASHC2A | c.2992G>T p.G998C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); called by mutect2, varscan2
- AC068580.4 | c.510C>T p.G170= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs749196696, COSV52589112; ClinVar: likely benign; called by mutect2, varscan2
- ACSM5 | c.243C>G p.V81= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV59375320; called by muse, mutect2, varscan2
- ADGRB1 | c.3840G>T p.P1280= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100029257, COSV60103877; called by muse, mutect2, varscan2
- ALG8 | c.444A>G p.L148= | Silent (SNP) | VAF 49/143 reads (34%) | catalogued as COSV55203364; called by muse, mutect2, varscan2
- AMZ1 | c.846G>A p.A282= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs150265717; called by mutect2, varscan2
- ASTN1 | c.1983G>A p.E661= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as rs1259644908, COSV56087776; called by muse, mutect2, varscan2
- ASXL3 | c.2154G>A p.P718= | Silent (SNP) | VAF 226/597 reads (38%) | catalogued as rs370185733, COSV52471685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AVIL | c.2451G>C p.G817= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV57684074; called by muse, mutect2, varscan2
- BOD1L1 | c.3222G>A p.R1074= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs774247658, COSV50077707; called by muse, mutect2, varscan2
- BRINP2 | c.192C>T p.P64= | Silent (SNP) | VAF 55/81 reads (68%) | catalogued as COSV64180703; called by muse, varscan2
- CIITA | c.2751C>T p.I917= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs771046803, COSV60855187; called by mutect2, varscan2
- CNTN3 | c.1185T>G p.V395= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV55185740; called by muse, mutect2, varscan2
- COL11A2 | c.4467C>A p.G1489= (on ENST00000341947 / NM_080680.3; = p.G1382= on NM_080679.2) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV59503244; called by muse, mutect2, varscan2
- DTX4 | c.675A>C p.G225= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV57095647; called by muse, varscan2
- DYNC2I2 | c.267G>A p.T89= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs137886760, COSV65548969; called by muse, varscan2
- FBN2 | c.8595C>A p.P2865= | Silent (SNP) | VAF 83/130 reads (64%) | catalogued as COSV52547681; called by muse, mutect2, varscan2
- G6PC | c.78C>T p.S26= | Silent (SNP) | VAF 44/75 reads (59%) | catalogued as COSV53833114; called by muse, mutect2, varscan2
- HOMER2 | c.189G>A p.P63= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs746991345, COSV58487283; called by mutect2, varscan2
- IFFO1 | c.1560C>G p.T520= (on ENST00000396840 / NM_001330324.2; = p.T523= on NM_080730.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV57522222; called by muse, mutect2, varscan2
- KHDRBS3 | c.337A>C p.R113= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV63424552; called by muse, mutect2, varscan2
- KIF14 | c.3882T>C p.D1294= | Silent (SNP) | VAF 68/88 reads (77%) | catalogued as COSV66264366; called by muse, mutect2, varscan2
- KLHL42 | c.348C>T p.S116= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs768351141, COSV67146275; called by muse, mutect2, varscan2
- LGALS9 | c.351C>A p.I117= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV56351591; called by mutect2, varscan2
- MLXIP | c.900C>T p.P300= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV59838285; called by muse, mutect2, varscan2
- NAGS | c.105G>A p.A35= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs771197434; called by mutect2, varscan2
- NDN | c.462C>T p.H154= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs1216970478; called by muse, mutect2, varscan2
- OR11A1 | c.324A>T p.L108= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV65821401; called by muse, mutect2, varscan2
- OR4K2 | c.141C>A p.I47= | Silent (SNP) | VAF 112/304 reads (37%) | catalogued as COSV53851913; called by mutect2, varscan2
- OR7A5 | c.375C>T p.A125= | Silent (SNP) | VAF 45/57 reads (79%) | catalogued as rs1479911810, COSV59235732; called by muse, mutect2, varscan2
- OR7C1 | c.762G>T p.T254= | Silent (SNP) | VAF 33/41 reads (80%) | catalogued as COSV99934846, COSV99934876; called by muse, mutect2, varscan2
- PLXNA4 | c.3768G>T p.V1256= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58158572; called by muse, mutect2, varscan2
- POLQ | c.2379G>T p.L793= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV51762565; called by muse, varscan2
- PRKCB | c.1698G>A p.K566= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as COSV57803976; called by muse, mutect2, varscan2
- PTER | c.612G>A p.R204= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV54347652; called by muse, mutect2, varscan2
- PTH2R | c.1167C>T p.L389= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs760814892, COSV55920810; called by mutect2, varscan2
- RIPOR2 | c.1602G>A p.E534= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as COSV52430105; called by muse, mutect2, varscan2
- RREB1 | c.2754C>A p.S918= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV58562999, COSV58566484; called by mutect2, varscan2
- SLC1A3 | c.87C>A p.A29= | Silent (SNP) | VAF 81/413 reads (20%) | catalogued as COSV54320877; called by muse, mutect2, varscan2
- SLC44A5 | c.1344G>A p.L448= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV63775583; called by mutect2, varscan2
- SLC4A8 | c.2841G>C p.V947= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as COSV60658697; called by muse, mutect2, varscan2
- SP8 | c.615C>T p.A205= (on ENST00000361443 / NM_198956.4; = p.A223= on NM_182700.6) | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV100815445; called by muse, mutect2, varscan2
- SPATA19 | c.12G>T p.T4= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV54482769, COSV54485347; called by muse, mutect2, varscan2
- SSX2IP | c.954C>T p.A318= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs374854979; called by muse, mutect2, varscan2
- SYBU | c.639G>A p.L213= (on ENST00000276646 / NM_001099754.2; = p.L212= on NM_017786.6) | Silent (SNP) | VAF 79/211 reads (37%) | catalogued as COSV52623486; called by muse, mutect2, varscan2
- SYT1 | c.594C>A p.V198= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV54077152; called by mutect2, varscan2
- SYT14 | c.1086G>A p.K362= | Silent (SNP) | VAF 83/106 reads (78%) | catalogued as COSV55054168, COSV55064583; called by muse, mutect2, varscan2
- TIE1 | c.1812T>A p.T604= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV65251641; called by muse, mutect2, varscan2
- VSIG2 | c.753G>T p.L251= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs745351513, COSV52519631; called by mutect2, varscan2
- OR56B4 | c.-2C>T | 5'UTR (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100337708; called by muse, mutect2, varscan2
- SPAG11A | chr8:7863537 G>T | 3'Flank (SNP) | VAF 20/175 reads (11%) | catalogued as COSV100429489; called by mutect2, varscan2
- UVSSA | c.*9545G>T | 3'UTR (SNP) | VAF 126/336 reads (38%) | catalogued as rs1355935242, COSV61351917; called by muse, varscan2
- ZNF467 | chr7:149776965 del C | 5'Flank (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
